Surgical pathology report (de-identified scan), TCGA case TCGA-90-A4ED, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site ABS - IUPUI, specimen TCGA-90-A4ED-01A (Primary Tumor).

[page 1 of 4]
Specimen Received:

A: 4R (FS)
B: Level 7 (FS)
C: Level 3 (FS)
D: #11 Lymph node
E: #10 Lymph node
F: #11 Lymph node #2
G: Right upper lobe (FS)
H: #11 Lymph node #3
I: Level 7 #2
J: 4R #2
K: 2R

1CD-0-3

carcinoma, squamous cell, nos 8070/3

Site: lung, upper lobe c34.1

hr
9/25/12

Addendum Report

Addendum Diagnosis

Rare organisms compatible with Histoplasma are identified on GMS special stain.

Final Pathologic Diagnosis:

- A. Lymph node, 4R, excisional biopsy:
One lymph node, negative for malignancy (0/1).
Sclerosing granuloma, consistent with histoplasmosis (GMS stain pending)
Frozen section diagnosis confirmed.
- B. Lymph node, level 7, excisional biopsy:
One lymph node, negative for malignancy (0/1).
Frozen section diagnosis confirmed.
- C. Lymph node, level 3, excisional biopsy:
One lymph node, negative for malignancy (0/1).
- D. Lymph node, #11, excisional biopsy:
One lymph node, negative for malignancy (0/1).
- E. Lymph node, #10, excisional biopsy:
One lymph node, negative for malignancy (0/1).
- F. Lymph node, #11 #2, excision:
Three lymph nodes, negative for malignancy (0/3)
- G. Lung, right, upper lobe, lobectomy:
Moderately differentiated squamous cell carcinoma see synoptic report for details.
All margins negative for malignancy.
Frozen section diagnosis confirmed.

Synoptic report:

Specimen: Right upper lobe
Procedure: Lobectomy
Specimen laterality: Right
Tumor site: Right upper lobe
Specimen integrity: Intact
Tumor size: 3.8 cm (greatest dimension)
Tumor focality: Unifocal

[page 2 of 4]
Tumor histologic type: Squamous cell carcinoma
Tumor grade: Moderately differentiated
Visceral pleura invasion: Not present
Tumor extension: Not applicable

Margins:

Bronchial margin: Uninvolved by invasive carcinoma
Vascular margin: Uninvolved by invasive carcinoma
Parenchymal margin: Uninvolved by invasive carcinoma
Parietal pleural margin: Not applicable
Chest wall margin: Not applicable
Other attached tissue margin: Not applicable

If all margins uninvolved by invasive carcinoma:

Distance of invasive carcinoma from closest margin: 1 mm
Specify margin: Parenchymal

Treatment effect: Not applicable
Lymph-vascular invasion: Present

Pathologic Staging (pTNM):

TNM Descriptors: None known
Primary tumor (pT): pT2a
Regional lymph nodes (pN): pN0
Number examined: 25 (including all parts)
Number involved: 0
Distant metastasis (pM): pMX

Additional pathologic findings: None

H. Lymph node, #11, #3, lymph node dissection:
Two lymph nodes, negative for malignancy (0/2).

I. Lymph node, level 7, #2, lymph node dissection:
Thirteen lymph nodes, negative for malignancy (0/13).

J. Lymph nodes, 4R, #2, excisional biopsy:
Thymus with benign thymic cyst.
Negative for malignancy.

K. Lymph node, 2R, excisional biopsy:
One lymph node, negative for malignancy (0/1)
Thymic tissue present.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Intraoperative Consult Diagnosis:

FSA: 4R:
Negative for tumor.

FSB: Level VII:
Negative for tumor.

FSC: Level III:
Negative for tumor.

[page 3 of 4]
FSA-FSC TAT: 29 mins/three frozen sections.

FSG: Right upper lobe bronchial margins:
Negative for tumor.
TAT: 11 mins.

Gross Description:

Received are eleven specimens, each labeled with the patient name

A is received fresh for intraoperative frozen section diagnosis and is additionally labeled, "4R" and consists of multiple fragments of black-tan tissues consistent with lymph node. These are submitted in its entirety for frozen section diagnosis. The remnants are transferred and submitted in their entirety in cassette A1.

B is received fresh for intraoperative frozen section diagnosis and is additionally labeled, "Level VII" and consists of multiple fragments of gray-tan to black-tan soft tissues minute to 0.7 cm. These are submitted in its entirety for frozen section diagnosis. The remnants are transferred and submitted in its entirety in cassette B1.

C is received fresh for intraoperative frozen section diagnosis and is additionally labeled, "Level III" and consists of multiple gray-tan to black-tan soft tissues 0.2 to 0.4 cm in greatest dimension. These are submitted in toto for frozen section diagnosis. The remnants are transferred and submitted in its entirety in cassette C1.

D is received in formalin and additionally labeled, "#11 lymph node" and consists of a single 0.8 x 0.6 x 0.3 cm black-tan soft tissue. The specimen is submitted in toto in cassette D.

E is received in formalin and is additionally labeled, "#10 lymph node" and consists of a single 0.6 x 0.5 x 0.3 cm black-tan soft tissue. The specimen is submitted in toto in cassette E.

F is received in formalin and additionally labeled, "#11 lymph node #2" and consists of three black-tan soft tissues 0.3 to 0.5 cm in greatest dimension. Submitted in toto in cassette F.

G is received fresh for intraoperative frozen section diagnosis and is additionally labeled, "right upper lobe bronchial margins." A portion of the tissue has been banked with the Tissue Bank. The specimen consists of a lobectomy specimen that is 11.5 x 5.4 x 3.5 cm. The pleural surface is purple-tan to yellow-tan, smooth and glistening with areas of anthracotic staining. At the time of frozen section diagnosis the bronchial margin was removed and submitted as FSG. This is now transferred and submitted in its entirety for permanent in cassette G1. Examination of the specimen reveals multiple stapled margins and now removed bronchial margins with bronchi containing apparent mucus plugging. These staples are removed from both parenchyma and apparent vascular margins. The stapled parenchymal margin is removed and the underlying tissue is inked black. The specimen is now step-sectioned to reveal a well-defined mass that is 3.8 x 1.2 x 2.3 cm. The mass abuts the pleura and is 0.1 cm from the parenchymal margin at its closest relationship. It is 3.1 cm from the bronchial margin and 3.5 cm from the nearest vascular margin. Further sectioning through the specimen reveals no additional masses. Representative sections from the specimen are now submitted as follows:

[page 4 of 4]
- G2 vascular margins;
- G3-5 mass to parenchymal margin;
- G6 mass to pleura;
- G7 additional mass;
- G8 uninvolved parenchyma.

H is received in formalin and additionally labeled, "#11 lymph node #3" and consists of two black-tan soft tissues 0.5 to 0.8 cm in greatest dimension. Submitted in toto in cassette H.

I is received in formalin and additionally labeled, "Level VII #2" and consists of an aggregate of black tan soft tissues 1.6 x 1.8 x 0.8 cm. Palpation through the specimen reveals multiple likely lymph nodes. The largest of which is 1.0 cm in greatest dimension. This node is bisected and submitted in its entirety in cassette I. The remaining soft tissues are submitted in its entirety in cassettes I2 and I3.

J is additionally labeled, "4R #2" and consists of 2.0 x 1.1 x 0.4 cm yellow-tan fatty soft tissue. Palpation through the specimen reveals no identifiable lymph nodes. The specimen is bisected and submitted in its entirety in cassette J1.

K is additionally labeled, "2R" and consists of a 2.3 x 0.8 x 0.7 cm yellow-tan fatty soft tissue. Palpation through the specimen does not reveal any grossly identifiable lymph nodes. The specimen is bisected and submitted in its entirety in cassette K.

END OF REPORT

Taken:

Gender: M

Notes		

9/18/12

Source: NCI Genomic Data Commons file 19f118ef-0622-43c1-8e6f-02cd8fa3d107 (TCGA-90-A4ED.D0C782A7-3180-4273-90C0-1A2F16FE293B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).